CCDI case PBCKUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/053f1c30-2230-4384-ab5a-087b9d433772

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (542 days).

Biospecimens (3 samples)
- Sample 0DUCRH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUCRN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUCU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
